Gene-level copy-number profile of tumor specimen TCGA-NC-A5HH-01A from TCGA case TCGA-NC-A5HH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 53.3 years (19,485 days).
Specimen TCGA-NC-A5HH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d450ed80-4ac0-4979-abd0-e3e46443c2f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/924af63b-58ea-4809-aafd-387adacc0730

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5; copy number 2: 3,793; copy number 3: 779; copy number 4: 35,941; copy number 5: 17; copy number 6: 14,098; copy number 7: 98; copy number 8: 3,439; copy number 9: 389; copy number 10: 244; copy number 11: 187; copy number 12: 303; copy number 14: 411; copy number 15: 50; copy number 17: 10; copy number 18: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HH-01A-11D-A26L-01): tumor purity 0.77, ploidy 2.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,745,095–64,833,232, 1 gene (within-gene range 0–4): RAVER2.
- chr2:1,795,525–1,828,667, 2 genes: AC093390.2, AC093390.1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,229 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,947,214–189,325,304, 1 gene, copy number 10 (within-gene range 8–10): TPRG1.
- chr3:189,238,686–198,222,513, 214 genes, copy number 10 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 12–15 (broad region; genes not listed).
- chr5:50,603,229–50,846,519, 4 genes, copy number 14 (within-gene range 4–14): AC112187.2, AC112187.1, AC112187.3, PARP8.
- chr6:131,573,966–132,273,332, 20 genes, copy number 11 (within-gene range 8–11): MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36.
- chr11:11,020,883–15,604,169, 75 genes, copy number 11–18 (within-gene range 8–18) (broad region; genes not listed).
- chr11:67,289,300–71,252,577, 137 genes, copy number 11–17 (within-gene range 4–17) (broad region; genes not listed).
- chr12:64,442,510–65,248,355, 28 genes, copy number 10: AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:65,281,657–65,286,728, 1 gene, copy number 10: AC026124.1.
- chr14:81,605,338–82,030,349, 6 genes, copy number 9 (within-gene range 4–9): LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1.
- chr18:7,566,782–8,406,861, 1 gene, copy number 9 (within-gene range 6–9): PTPRM.
- chr18:7,995,570–9,402,420, 32 genes, copy number 9: U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
